Somatic mutation profile of tumor specimen 0DAF27 from CCDI case PBBJSS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 14.2 years (5,180 days).
Specimen 0DAF27: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 598b9c26-187d-47b8-b2c5-ff0a63c704d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAF1H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea68f39-b4a5-43e6-b1c1-341f98ca5883

The open-access MAF lists 4 somatic variants for this specimen: 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 12/297 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 8/252 reads (3%) | called by muse, mutect2
- C7orf65 | n.478A>T | RNA (SNP) | VAF 132/466 reads (28%) | called by muse, mutect2, varscan2
- KCNJ3 | chr2:154698676 C>A | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
